Somatic mutation profile of tumor specimen TCGA-ZM-AA0D-01A (aliquot TCGA-ZM-AA0D-01A-11D-A435-10) from TCGA case TCGA-ZM-AA0D, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 34.9 years (12,738 days).
Specimen TCGA-ZM-AA0D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99562a00-a974-49d4-8075-c911fab5726c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZM-AA0D-10A (Blood Derived Normal), aliquot TCGA-ZM-AA0D-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37a4d60a-f563-4ea0-85b5-6547feb7801f

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 4, Silent 3, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2446G>T p.D816Y | Missense Mutation (SNP) | VAF 8/82 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs121913506, COSV55386862, COSV55387240, COSV55408330; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- RANBP2 | c.5861C>T p.T1954I | Missense Mutation (SNP) | VAF 78/1050 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV51696782; called by muse, mutect2
- SMOX | c.463del p.R155Gfs*39 | Frame Shift Del (DEL) | VAF 11/120 reads (9%) | catalogued as COSV53862922; called by mutect2, pindel
- AGBL4 | c.194A>G p.E65G | Missense Mutation (SNP) | VAF 32/346 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SALL4 | c.827G>A p.S276N | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SORL1 | c.4491C>A p.C1497* | Nonsense Mutation (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2
- KANSL1 | c.534G>A p.G178= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as COSV52267939; called by muse, mutect2
- SMARCA1 | c.1737C>T p.L579= | Silent (SNP) | VAF 25/200 reads (13%) | catalogued as rs1454559272; called by muse, mutect2, varscan2
- WNK2 | c.3315C>T p.A1105= | Silent (SNP) | VAF 7/102 reads (7%) | catalogued as rs1210228642; called by muse, mutect2
